Gene-level copy-number profile of tumor specimen ALCH-AEZ0-TTP1-A from ALCHEMIST case ALCH-AEZ0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.5 years (27,208 days).
Specimen ALCH-AEZ0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d2dd68d1-afef-4c28-9ba4-f04ea1a0082d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEZ0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/6f7b496b-5119-4f91-8398-d9bae57b4c64

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 5,435; copy number 2: 48,945; copy number 3: 3,975; copy number 4: 9.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:232,343,116–232,536,667, 14 genes (within-gene range 0–2): NRBF2P6, ECEL1P3, AC068134.3, ALPP, AC068134.1, ECEL1P2, ALPG, ECEL1P1, AC068134.2, DIS3L2P1, ALPI, ECEL1, PRSS56, CHRND.
- chr3:52,777,595–52,809,009, 2 genes: ITIH1, ITIH3.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–1): CRB2.
- chr9:123,402,525–123,402,603, 1 gene (within-gene range 0–1): MIR601.
- chr15:25,232,387–25,250,940, 11 genes (within-gene range 0–2): SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:77,568,970–77,608,888, 1 gene: AC046168.2.
- chr16:56,351,886–56,353,524, 1 gene (within-gene range 0–2): AC009102.2.
- chr17:3,510,502–3,557,812, 1 gene (within-gene range 0–1): TRPV3.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–1): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,434. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
